Somatic mutation profile of tumor specimen 0DQ2NF from CCDI case PBCEER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,680 days).
Specimen 0DQ2NF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2250c2b8-8c8a-4466-8eb5-2f5ec2ffec35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2OX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a91f9949-8def-49a5-b441-5d1e507ec8f2

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LARS2 | c.*276C>T | 3'UTR (SNP) | VAF 120/554 reads (22%) | catalogued as rs398123036, CM132510, COSV55527677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP400 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 100/387 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748689018; called by muse, mutect2, varscan2
- HINT3 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 22/562 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2
- TG | c.8092A>G p.K2698E | Missense Mutation (SNP) | VAF 36/625 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TMEM200A | c.1303A>T p.N435Y | Missense Mutation (SNP) | VAF 21/674 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- BTAF1 | c.3723A>T p.R1241= | Silent (SNP) | VAF 75/403 reads (19%) | called by muse, mutect2, varscan2
- CFAP157 | c.570G>A p.S190= | Silent (SNP) | VAF 129/725 reads (18%) | catalogued as rs367946787; called by muse, mutect2, varscan2
- SS18 | c.948T>C p.D316= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- CAPS2 | c.1670-2548G>A | Intron (SNP) | VAF 13/238 reads (5%) | called by muse, mutect2
- CNTN1 | c.1805-9322C>A | Intron (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
